Gene-level copy-number profile of tumor specimen TCGA-53-7624-01A from TCGA case TCGA-53-7624, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 40.5 years (14,794 days).
Specimen TCGA-53-7624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9f9ff9c7-420d-4cab-a648-3f661db07340.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-53-7624-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d075b56f-d5f3-4424-84cb-f6ea28dc7097

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 2,759; copy number 2: 19,738; copy number 3: 16,725; copy number 4: 16,615; copy number 5: 2,853; copy number 6: 1,039; copy number 7: 26; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-53-7624-01A-11D-2062-01): tumor purity 0.69, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr9:20,999,509–22,824,213, 57 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,919 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,267,798–211,207,138, 37 genes, copy number 5 (within-gene range 4–5): ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2, CAMK1G, LAMB3, MIR4260, HSD11B1-AS1, G0S2, HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25, SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1.
- chr1:215,005,775–215,377,374, 2 genes, copy number 6: KCNK2, VDAC1P10.
- chr2:2,638,178–3,157,797, 8 genes, copy number 5: AC018685.2, AC018685.3, AC011995.2, AC018685.1, AC011995.1, LINC01250, AC019118.2, AC019118.1.
- chr2:19,711,715–21,044,073, 36 genes, copy number 6 (within-gene range 4–6): AC019055.1, CISD1P1, LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH, LINC02850, AC115619.1, APOB, AC010872.1.
- chr2:100,722,221–140,221,485, 717 genes, copy number 5 (broad region; genes not listed).
- chr2:140,234,737–140,234,923, 1 gene, copy number 5: AC092156.1.
- chr3:138,652,698–139,389,736, 20 genes, copy number 5 (within-gene range 3–5): PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6.
- chr3:139,452,884–139,539,829, 4 genes, copy number 5: RBP2, AC097103.1, ACTG1P1, RBP1.
- chr4:41,359,607–41,700,044, 1 gene, copy number 6 (within-gene range 4–6): LIMCH1.
- chr4:41,608,312–42,892,618, 26 genes, copy number 6: AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82.
- chr4:51,843,000–62,078,335, 151 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr4:89,111,533–89,999,409, 13 genes, copy number 6: TIGD2, AC104785.1, RNU6-907P, GPRIN3, AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1.
- chr7:11,820,317–16,833,433, 50 genes, copy number 5–8: THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2.
- chr7:51,016,212–62,275,678, 187 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:93,646,066–93,647,092, 1 gene, copy number 7: ZNF317P1.
- chr10:32,446,140–32,882,874, 1 gene, copy number 6 (within-gene range 2–6): CCDC7.
- chr10:32,887,273–34,875,422, 25 genes, copy number 6: ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1.
- chr10:75,089,248–87,553,461, 217 genes, copy number 5 (broad region; genes not listed).
- chr11:121,674,261–135,075,908, 290 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:66,767–4,118,132, 100 genes, copy number 5 (broad region; genes not listed).
- chr12:40,554,161–41,574,745, 6 genes, copy number 5 (within-gene range 4–5): RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1.
- chr12:81,868,368–82,686,632, 10 genes, copy number 6: AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1.
- chr13:29,764,371–30,196,881, 11 genes, copy number 7: UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1.
- chr15:59,132,434–59,372,871, 1 gene, copy number 5 (within-gene range 3–5): MYO1E.
- chr15:59,206,843–72,686,182, 321 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:27,638,483–48,758,333, 914 genes, copy number 5–6 (broad region; genes not listed).
- chr19:52,031,378–52,095,738, 1 gene, copy number 5 (within-gene range 4–5): ZNF432.
- chr19:52,058,490–58,605,223, 509 genes, copy number 5 (broad region; genes not listed).
- chr20:31,274,170–36,863,538, 210 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr21:31,060,600–33,123,725, 49 genes, copy number 5: UBE3AP2, TIAM1, AP000248.1, AP000563.1, AP000251.1, FBXW11P1, AP000253.1, SOD1, AP000254.1, AP000254.2, SCAF4, HMGN1P2, AP000255.1, TPT1P1, HUNK, HUNK-AS1, LINC00159, AP000265.1, MIS18A, MIS18A-AS1, MRAP, MRAP-AS1, URB1, SNORA80A, URB1-AS1, CFAP298-TCP10L, EVA1C, EXOSC3P1, TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1, SYNJ1, PAXBP1-AS1, PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1.

Autosomal genes at a single copy (total copy number 1): 1,842. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
